Surgical pathology report (de-identified scan), TCGA case TCGA-C5-A8XJ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-C5-A8XJ-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: F

DOB: [REDACTED]

(Age: [REDACTED])

Physician(s): [REDACTED]

M.D.

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Received: [REDACTED]

Reported: [REDACTED]

ICD O-3

Carcinoma, squamous cell
NOS

Site: Cervix NOS

Q10 1/17/14

DIAGNOSIS

UTERUS, CERVIX, BIOPSY [REDACTED]

- DETACHED FRAGMENTS OF SQUAMOUS CELL CARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED] M.D.

***Report Electronically Reviewed and Signed Out By [REDACTED]

M.D.***

Microscopic Description and Comment

Microscopic examination substantiates the above cited diagnosis.

History

The patient is a [REDACTED] year old woman.

Material(s) Received

Received are two slides labeled [REDACTED] accompanied by a corresponding pathology report. The material originates from [REDACTED]

Physician Copy [REDACTED]

END OF REPORT

Source: NCI Genomic Data Commons file 4450d0f1-0891-493c-8763-2887e2baf6a5 (TCGA-C5-A8XJ.0758C57C-F182-48E1-BEA7-27C5B9206FB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).